Somatic mutation profile of tumor specimen TCGA-MW-A4EC-01A (aliquot TCGA-MW-A4EC-01A-11D-A25V-10) from TCGA case TCGA-MW-A4EC, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 73.0 years (26,649 days).
Specimen TCGA-MW-A4EC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c40dec99-386c-4413-8f11-28103025d899.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MW-A4EC-10A (Blood Derived Normal), aliquot TCGA-MW-A4EC-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/83d750c6-1b87-460b-a059-106bbf7a963c

The open-access MAF lists 46 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Frame Shift Del 5, Splice Site 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGO4 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV100943009; called by muse, mutect2, varscan2
- ANO1 | c.233C>A p.T78N | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100304191; called by muse, mutect2, varscan2
- CDK13 | c.4131G>T p.L1377F | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as COSV51697408; called by muse, mutect2, varscan2
- CLDN16 | c.400G>A p.G134S | Missense Mutation (SNP) | VAF 42/200 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99290248; called by muse, mutect2, varscan2
- EIF2S3 | c.1347A>T p.K449N | Missense Mutation (SNP) | VAF 71/242 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV99450953; called by muse, mutect2, varscan2
- IGSF6 | c.347A>G p.Y116C | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99193644; called by muse, mutect2, varscan2
- ITGB7 | c.2011G>A p.A671T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.304); catalogued as COSV99914146; called by muse, mutect2, varscan2
- KIF5C | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs1357129507, COSV101276159; called by muse, varscan2
- MAGEE2 | c.776G>T p.R259M | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.478); catalogued as COSV100973154; called by muse, mutect2, varscan2
- NEUROD2 | c.1142A>G p.H381R | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs1366328120, COSV100223152; called by muse, mutect2, varscan2
- NUDT21 | c.215A>G p.D72G | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.196); catalogued as COSV55859461; called by muse, mutect2, varscan2
- OPLAH | c.271C>G p.R91G | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV101470788; called by muse, mutect2, varscan2
- OR4N2 | c.287G>A p.G96D | Missense Mutation (SNP) | VAF 73/245 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as rs370388773; called by muse, mutect2, varscan2
- OR52M1 | c.469T>C p.Y157H | Missense Mutation (SNP) | VAF 12/283 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV64171583; called by muse, mutect2
- OTUD4 | c.1458C>G p.S486R (on ENST00000447906 / NM_001366057.1; = p.S421R on NM_001102653.1) | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.693); catalogued as COSV101486013; called by muse, mutect2, varscan2
- PDE7B | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.524); catalogued as COSV100367902; called by muse, mutect2, varscan2
- PSMD12 | c.1134G>C p.M378I | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.123); catalogued as COSV100635372; called by muse, mutect2, varscan2
- RBBP6 | c.4508G>A p.R1503Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as rs780815708, COSV100154539, COSV60506340; called by muse, mutect2, varscan2
- SLC26A2 | c.717T>G p.F239L | Missense Mutation (SNP) | VAF 220/488 reads (45%) | SIFT tolerated (0.91); PolyPhen benign (0.059); catalogued as COSV99640220; called by muse, mutect2, varscan2
- SNX14 | c.339-1G>C p.X113_splice | Splice Site (SNP) | VAF 25/77 reads (32%) | catalogued as COSV100121623, COSV59012459; called by muse, mutect2, varscan2
- SPTB | c.1795+2T>A p.X599_splice | Splice Site (SNP) | VAF 8/148 reads (5%) | catalogued as COSV101072252; called by muse, mutect2
- TCOF1 | c.4463T>C p.V1488A (on ENST00000377797 / NM_001135243.1; = p.V1411A on NM_000356.4) | Missense Mutation (SNP) | VAF 103/455 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.038); catalogued as COSV99153946; called by muse, mutect2, varscan2
- TGFB3 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 36/122 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV99466313; called by mutect2, varscan2
- TTN | c.16283G>C p.G5428A (on ENST00000591111; = p.G4501A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/85 reads (22%) | PolyPhen benign (0.337); catalogued as COSV100619231; called by muse, mutect2, varscan2
- USE1 | c.89G>T p.W30L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99812532; called by muse, mutect2, varscan2
- VHL | c.473T>G p.L158R | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM164440, CM941379, COSV56543253, COSV56550270, COSV56558440, COSV56563690; called by muse, mutect2, varscan2
- CHRD | c.2701_2706del p.R901_C902del | In Frame Del (DEL) | VAF 24/109 reads (22%) | called by mutect2, pindel*, varscan2*
- FTMT | c.374A>T p.H125L | Missense Mutation (SNP) | VAF 10/236 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- HYLS1 | c.570_606del p.R191* | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- NIPBL | c.2506del p.D836Ifs*11 | Frame Shift Del (DEL) | VAF 48/259 reads (19%) | called by mutect2, pindel, varscan2
- SLC2A10 | c.1284del p.P429Qfs*2 | Frame Shift Del (DEL) | VAF 13/44 reads (30%) | called by mutect2, pindel, varscan2
- TBL1X | c.803del p.G268Afs*7 | Frame Shift Del (DEL) | VAF 33/137 reads (24%) | called by mutect2, pindel, varscan2
- TMEM65 | c.563_564del p.I188Tfs*2 | Frame Shift Del (DEL) | VAF 34/127 reads (27%) | called by mutect2, pindel, varscan2
- ABCA9 | c.4080C>T p.P1360= | Silent (SNP) | VAF 28/84 reads (33%) | catalogued as rs763480191, COSV60631455; called by muse, mutect2
- ADAMTS8 | c.1692C>T p.Y564= | Silent (SNP) | VAF 36/111 reads (32%) | catalogued as COSV99961169; called by muse, mutect2, varscan2
- COMTD1 | c.228C>T p.T76= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV100041007; called by muse, mutect2, varscan2
- FEZF1 | c.597C>T p.A199= | Silent (SNP) | VAF 34/135 reads (25%) | catalogued as COSV100484485; called by muse, mutect2, varscan2
- JAKMIP3 | c.2373C>T p.A791= | Silent (SNP) | VAF 20/45 reads (44%) | catalogued as COSV100059444; called by muse, mutect2, varscan2
- KIF13A | c.3972G>A p.L1324= | Silent (SNP) | VAF 47/288 reads (16%) | catalogued as rs1362646564, COSV99436650; called by muse, mutect2, varscan2
- KY | c.415C>A p.R139= | Silent (SNP) | VAF 23/248 reads (9%) | catalogued as COSV101415008; called by muse, mutect2
- MOV10L1 | c.846A>C p.L282= | Silent (SNP) | VAF 19/93 reads (20%) | catalogued as COSV99434261; called by muse, mutect2, varscan2
- MYCN | c.1245G>A p.E415= | Silent (SNP) | VAF 39/108 reads (36%) | catalogued as COSV99808379; called by muse, mutect2, varscan2
- NTSR1 | c.444C>T p.R148= | Silent (SNP) | VAF 22/48 reads (46%) | catalogued as rs1185324665, COSV65139175; called by muse, mutect2, varscan2
- RTL9 | c.4125A>C p.G1375= | Silent (SNP) | VAF 47/188 reads (25%) | catalogued as COSV101511731; called by muse, mutect2, varscan2
- KRT18P55 | n.1168C>T | RNA (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- SPATA8 | n.728G>A | RNA (SNP) | VAF 53/150 reads (35%) | catalogued as rs749662907, COSV60705216; called by muse, mutect2, varscan2
